TARGET case TARGET-20-PAUXNR — Acute Myeloid Leukemia (TARGET-AML)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Myeloid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/86dffc23-e93e-4ccb-99f1-632b73b6d634

Demographics
Sex at birth: female; Race: asian; Ethnicity: not hispanic or latino; Age at index: 11 years; Vital status: Alive.

Diagnoses (1)
1. Acute myeloid leukemia, NOS: ICD-O-3 morphology code: 9861/3; ICD-10 code: C92.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 11.2 years (4,076 days); Year of diagnosis: 2012; Days to last follow up: 2,652 days (7.3 years).
   Treatment given: Reason treatment ended: Course of Therapy Completed; Course number: 1; Timepoint category: End of Treatment Course.
   Treatment given: Reason treatment ended: Course of Therapy Completed; Course number: 2; Timepoint category: End of Treatment Course.
   Treatment given: Protocol identifier: AAML0631.
   Recorded as not given: Stem Cell Transplantation, NOS, first complete response.

Follow-up (2 entries)
- Days to follow up: 1,425 days (3.9 years); Days to first event: 1,425 days (3.9 years); First event: Second Malignant Neoplasm.
- Days to follow up: 2,652 days (7.3 years); Year of follow up: 2019.

Molecular and laboratory tests (laboratory values one line per visit day)
- Day 0: Leukocytes 29 ×10³/µL; Blast Count 76%.

Biospecimens (1 sample)
- Sample TARGET-20-PAUXNR-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_AML_ClinicalData_AAML1031_AAML0631_additionalCasesForSortedCellsAndCBExperiment_20230720.xlsx:
- Overall Survival Time in Days: 2652
- WBC at Diagnosis: 29
- Peripheral blasts (%): 76
- Chloroma: No
- FAB Category: M3
- Cytogenetic Complexity: >6
- Primary Cytogenetic Code: PML-RARA
- ISCN: 46,XX,t(4;12)(q21;q13),del(6)(q15q23),del(7)(q22q32),t(12;19)(p13;q13.1),del(13)(q14q22),t(14;21)(q24;q11.2),t(15;17)(q24;q21)[6]/46,XX,t(15;17)(q24;q21)[14]
- SCT in 1st CR: No
